Somatic mutation profile of tumor specimen TARGET-10-PASMNV-09A (aliquot TARGET-10-PASMNV-09A-01D) from TARGET case TARGET-10-PASMNV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,662 days).
Specimen TARGET-10-PASMNV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed89bc22-220c-458c-a914-f1dfa5ceb542.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASMNV-10A (Blood Derived Normal), aliquot TARGET-10-PASMNV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc6540da-7301-4d5f-a4ae-6463651a5347

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Splice Site 1, In Frame Ins 1, Intron 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.3303+2T>C p.X1101_splice (on ENST00000506720 / NM_001322402.2; = p.X1033_splice on NM_015236.6) | Splice Site (SNP) | VAF 27/64 reads (42%) | catalogued as COSV72229160; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.446A>G p.D149G | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.266); catalogued as COSV57278117; called by muse, mutect2, varscan2
- CCDC102B | c.1092C>A p.D364E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.164); catalogued as COSV60133944; called by muse, mutect2, varscan2
- HSD17B2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs369773984; called by muse, mutect2, varscan2
- LRMDA | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as COSV57983590; called by muse, mutect2, varscan2
- NAPSA | c.236T>C p.F79S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV53796662; called by muse, mutect2, varscan2
- NOTCH1 | c.5027T>A p.V1676D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53026269; called by muse, mutect2, varscan2
- NXPE1 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs78257939; called by muse, mutect2, varscan2
- PIK3R1 | c.1356_1357insCCA p.Y452_N453insP (on ENST00000521381 / NM_181523.3; = p.Y182_N183insP on NM_181504.4) | In Frame Ins (INS) | VAF 3/32 reads (9%) | catalogued as COSV57123208, COSV57135448, COSV57138512; called by mutect2, pindel
- PPT2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs776105874, COSV61353817; called by muse, mutect2, varscan2
- RAB23 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV58097246; called by muse, mutect2, varscan2
- RGS6 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs368125974, COSV59563439; called by muse, mutect2, varscan2
- S100A13 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV59884348; called by muse, mutect2, varscan2
- SLC1A7 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV65194231; called by muse, mutect2, varscan2
- KDM6A | c.3335_3341delinsATTAT p.V1112Dfs*38 | Frame Shift Del (DEL) | VAF 20/22 reads (91%) | called by pindel, varscan2*
- TEDC1 | c.1031C>T p.P344L (on ENST00000392523 / NM_001367178.1; = p.P275L on NM_001134875.1) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.531); called by muse, mutect2
- HMCN2 | c.543T>C p.A181= | Silent (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- HOXC8 | c.273C>T p.Y91= | Silent (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2745G>A p.S915= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as rs778810329; called by muse, mutect2, varscan2
- ZNF276 | c.1296C>T p.T432= (on ENST00000443381 / NM_001113525.2; = p.T357= on NM_152287.4) | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs1443012259; called by muse, mutect2, varscan2
- EBF3 | c.*59G>A | 3'UTR (SNP) | VAF 45/105 reads (43%) | catalogued as rs906307380; called by muse, mutect2, varscan2
- EIF4E1B | c.296+64G>A | Intron (SNP) | VAF 21/35 reads (60%) | catalogued as rs946437043; called by muse, mutect2, varscan2
